CPTAC case C3L-01232 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3b00a1c2-4d04-428d-b7eb-661bc52eb22e

Demographics
Sex at birth: female; Race: white; Year of birth: 1966; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 51.6 years (18,836 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 744 days (2.0 years); Progression or recurrence: no; Days to last follow up: 744 days (2.0 years).
   Pathology details: Greatest tumor dimension: 4 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Hormone Therapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 378 days (1.0 years); Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 1.
- Days to follow up: 744 days (2.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 238 days; Karnofsky performance status: 40; ECOG performance status: 2.
- Days to follow up: 744 days (2.0 years); Disease response: With Tumor; Karnofsky performance status: 40; ECOG performance status: 2.

Other clinical attributes
- Weight: 63 kg; Height: 157 cm; BMI: 25.56.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01232-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 321 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01232-24: Section location: Left Hemisphere; Percent tumor nuclei: 80; Percent necrosis: 25.
- Sample C3L-01232-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -4 days; Method of sample procurement: Blood Draw.
